Gene-level copy-number profile of tumor specimen TCGA-04-1542-01A from TCGA case TCGA-04-1542, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 52.7 years (19,263 days).
Specimen TCGA-04-1542-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.d346cd40-dcdc-4a57-8a9d-b20544c87d5f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1542-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dd15bf99-b6d9-4a3e-b66a-b6ce47fd6d08

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,565; copy number 2: 23,917; copy number 3: 10,735; copy number 4: 13,783; copy number 5: 4,412; copy number 6: 2,926; copy number 7: 261; copy number 8: 189; copy number 9: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1542-01A-01D-0497-01): tumor purity 0.94, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,815 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,254,424–159,055,155, 34 genes, copy number 5: CD1A, HMGN1P5, CD1C, CD1B, CD1E, OR10T2, OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P, OR10R1P, HSP90AA3P, OR6Y1, OR6P1, OR10X1, OR10Z1, SPTA1, OR6K1P, OR6K2, OR6K3, OR6K4P, OR6K5P, OR6N1, OR6K6, OR6N2, OR2AQ1P, OR10AA1P, MNDA, PYHIN5P, PYHIN1, IFI16.
- chr1:159,081,133–159,081,795, 1 gene, copy number 5: RAD1P2.
- chr1:185,558,371–187,686,628, 22 genes, copy number 5 (within-gene range 3–5): LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1, AL133553.1, AL133553.2, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, AL049198.1, PTGS2, PACERR, PLA2G4A, LINC01036, AL391813.1.
- chr1:200,739,558–248,919,946, 1,122 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr2:115,079,354–115,468,938, 3 genes, copy number 5: AC093610.1, DPP10-AS1, RPSAP23.
- chr2:116,687,218–120,466,218, 54 genes, copy number 5–6: AC104408.1, AC062016.1, MTCYBP39, AC062016.2, MTND1P28, MTND2P21, MTCO1P43, RNU7-190P, AC092170.1, AC064856.1, AC009312.1, DDX18, AC009404.1, HTR5BP, CCDC93, AC009303.1, AC009303.2, AC009303.3, AC009303.4, RN7SL111P, INSIG2, THORLNC, LINC01956, EN1, MARCO, AC013457.1, C1QL2, RN7SL468P, STEAP3, STEAP3-AS1, C2orf76, DBI, TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB, LINC01101.
- chr3:143,265,222–143,848,485, 1 gene, copy number 5 (within-gene range 4–5): SLC9A9.
- chr3:143,503,275–146,606,216, 25 genes, copy number 5: GAPDHP47, ST13P15, AC073358.1, AC107421.1, DIPK2A, RNA5SP144, AC011592.1, LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1.
- chr3:171,058,414–198,222,513, 538 genes, copy number 5 (broad region; genes not listed).
- chr4:186,426,546–190,092,279, 70 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:1,931,064–4,147,429, 21 genes, copy number 5 (within-gene range 4–5): AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063.
- chr5:17,684,584–26,013,025, 76 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:26,669,346–29,983,114, 33 genes, copy number 5: AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, AC112172.2, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1.
- chr7:48,171,458–49,921,950, 12 genes, copy number 5 (within-gene range 4–5): ABCA13, AC091770.1, LINC02838, AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1, DDX43P2, AC092448.1, AC093775.1, VWC2.
- chr7:142,252,143–148,420,998, 194 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:41,509,593–41,578,421, 1 gene, copy number 6 (within-gene range 3–6): AC009630.1.
- chr8:41,540,381–100,350,707, 904 genes, copy number 5–6 (broad region; genes not listed).
- chr8:100,382,763–100,382,845, 1 gene, copy number 5: MIR4471.
- chr8:100,572,889–144,118,328, 629 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr11:68,261,338–69,738,017, 37 genes, copy number 5: C11orf24, AP002813.1, LRP5, PPP6R3, NDUFA3P2, AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5.
- chr11:71,563,389–90,915,052, 458 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr11:95,789,965–97,259,987, 17 genes, copy number 6: CEP57, MTMR2, RNA5SP345, AP000870.1, MAML2, AP000779.1, MIR1260B, CCDC82, JRKL, JRKL-AS1, RNA5SP346, LINC02737, AP003066.1, AP003066.2, MED28P5, AP001836.1, LINC02553.
- chr12:66,767–34,249,958, 850 genes, copy number 5–6 (broad region; genes not listed).
- chr16:11,555–1,000,926, 89 genes, copy number 5 (broad region; genes not listed).
- chr16:1,938,229–28,240,668, 765 genes, copy number 5 (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 6 (broad region; genes not listed).
- chr18:27,335,968–27,595,164, 1 gene, copy number 5 (within-gene range 4–5): AC090403.1.
- chr18:27,418,884–32,938,316, 74 genes, copy number 5–7 (broad region; genes not listed).
- chr18:32,954,075–32,957,998, 1 gene, copy number 7: AC090371.1.
- chr19:12,730,640–20,965,140, 441 genes, copy number 6–8 (broad region; genes not listed).
- chr19:21,709,522–22,368,952, 29 genes, copy number 5: MTDHP4, VN1R84P, ZNF100, CCNYL6, AC092364.1, BRI3BPP1, ZNF43, BNIP3P27, ZNF208, MTDHP2, AC003973.2, BNIP3P28, AC003973.1, ZNF257, BNIP3P29, ZNF92P2, AC073539.2, PCGF7P, MTDHP5, VN1R85P, ZNF676, BNIP3P30, AC073539.14, AC073539.1, AC073539.3, ZNF729, BNIP3P31, AC011494.1, RPL34P34.
- chr19:27,638,483–37,730,733, 342 genes, copy number 6–9 (broad region; genes not listed).
- chr20:87,250–16,053,197, 287 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:15,552,157–31,801,805, 307 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,144. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
